CCDI case PBCNIR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/9af05b05-f2a4-486f-8545-735c9f21c012

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 2.0 years (722 days).

Biospecimens (3 samples)
- Sample 0DVZEE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVZEK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVZEP: Tissue type: Tumor; Specimen type: Solid Tissue.
